Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A705, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A705-01A (Primary Tumor).

[page 1 of 2]
PAGE 1

SURGICAL PATHOLOGY REPORT

Name	Age/Sex	Attend Dr.
Root	Status	Location
Reg	DOB	

Specimen: 7 Spec Date: Spec Type: Status:
Rec'd Date: Subm Dr:

DIAGNOSIS

EXCISION CARDIAC PARAGANGLIOMA 4.5 CM;
- PARAGANGLIOMA

PRE-OP DIAGNOSIS

Cardiac paraganglioma

POST-OP DIAGNOSIS

Same

GROSS DESCRIPTION

The specimen is received fresh labeled with the patient's name and "cardiac paraganglioma". It consists of a single discrete firm nodular fragment of pinkish-tan tissue with an aggregate weight of 21 grams and measures 4.5 x 3.3 x 1.8 cm. Sections reveal is a homogenous tan focally calcified surface. Part of the specimen is sent to as requested. Totally submitted in 13 cassettes.

Summary of sections:

1-13) tumor - 13

MICROSCOPIC DESCRIPTION

Total of thirteen H&E stained slides along with Chromogranin and pancytokeratin stains are reviewed. Tumor cells are negative for Pancytokeratin and positive for Chromogranin. No necrosis or increased mitosis is seen.

The information contained in this report is privileged and confidential. If you are not the intended recipient, disclosure, copying, distribution, or taking of any action in reliance of its contents is strictly prohibited. If you have received this in error, please notify us immediately.

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

<DIS IN

Specimen: Received: Status:
COPIES TO: Spec Type: Subm

MD, OTHER PHYSICIAN
NONE
NONE, NA 00000
NONE

VIEWED AND ELECTRONICALLY SIGNED BY
(Signature on file)

The information contained in this report is privileged and confidential. If you are not the intended recipient, disclosure, copying, distribution, or taking of any action in reliance of its contents is strictly prohibited. If you have received this in error, please notify us immediately.

** END OF REPORT **

Dual/Synchronous Primary Noted	para	✓
Reviewed/Initials	Date Reviewed	

hw 7/26/13

RML 7/26/13

Source: NCI Genomic Data Commons file dbe8a39e-ce34-4830-a4af-1accc4e11808 (TCGA-QR-A705.90AD858C-5A35-4CB4-8263-E3805322CB7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).